TARGET case TARGET-15-SJMPAL022667 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/271c3985-4f72-451b-83ca-3d30858ab334

Demographics
Sex at birth: male; Age at index: 16 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 16.3 years (5,943 days); Year of diagnosis: 2008; Days to last follow up: 2,666 days (7.3 years).

Follow-up (1 entry)
- Days to follow up: 2,666 days (7.3 years); Event-free: no event (relapse, second malignancy or death) recorded through day 2,666; Year of follow up: 2015.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 62.5 ×10³/µL.

Biospecimens (1 sample)
- Sample TARGET-15-SJMPAL022667-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 2666
- Protocol: St. Jude
- WBC at Diagnosis: 62.5
- Initial Therapy: AML
- Karyotype: 46,XX,der(7)r(7;?)(p22q36;?),add(7)(q22)[17]/46,XX[3]
- WHO ALAL Classification: T/M
- WHO Dx: T/M
